Surgical pathology report (de-identified scan), TCGA case TCGA-ES-A2HT, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Florida, specimen TCGA-ES-A2HT-01A (Primary Tumor).

[page 1 of 2]
Patier

Medic

Age:

Sex: M

Service Date:

Accession #:

N

ICD-0-3

Carcinoma, hepatocellular, NOS 8190/3

Site: Liver C22.0 *LS 6/16/11*

Patient's location:

Report type: Surgical

Date Obtained:

Date Received:

Referring Physician/Surgeon(s):

ID

Service: Transplant Surgery

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Segment IVB and V of liver

A. Trichrome-Masson-Blue

CLINICAL HISTORY

year old male with history of hepatitis C and hepatocellular carcinoma.

GROSS DESCRIPTION: Received the following specimen(s) in the Department of Pathology, labeled with the patient's name and hospital #:

A. Segment IVB and V of liver

A. The specimen is received fresh and consists of a 285 gm wedge shaped portion of liver that measures 15.0 x 10.0 x 5.5 cm. The gallbladder is attached to the posterior aspect. Two sides of the specimen are cauterized and irregular and the other side is covered by glistening smooth capsule. A 2.2 cm diameter subcapsular nodule partially distorts the anterior surface of segment IVB. The nodule is yellow-green and well-circumscribed. It distends the capsule 0.4 cm. The nodule is 1.9 cm from the nearest cauterized margin. The tumor does not invade the vessel adjacent to the mass. The gallbladder is 11.0 x 5.0 x 4.0 cm and is filled with tenacious thick green bile and multiple gray-black calculi. The calculi are 0.4 cm in maximum diameter. A small amount of black sludge is also included. The gallbladder mucosa is granular and gray-tan. The surrounding liver is tan to red-brown and not cirrhotic. Representative sections are submitted as follows:

- A1 Vein at IVB margin
- A2 Nearest cauterized margin and tumor
- A3-A6 Tumor in adjacent liver
- A7 Normal liver
- A8 Gallbladder

DIAGNOSIS:

A. Segment IVB and V of liver, partial hepatectomy:

Moderately-differentiated hepatocellular carcinoma with the following features:

- Solitary nodule measuring 2.2 cm in greatest dimension.
- No vascular invasion identified.
- Resection margin is widely negative.
- AJCC pathologic staging **pT1NXMX**; TNM staging required by managing physician.

Ancillary diagnoses:

- Background liver with moderate chronic active hepatitis, HAI grade 5 (2 + 0 + 1 + 2) and bridging fibrosis (fibrosis stage 4 out of 6), consistent with hepatitis C infection.
- Gallbladder with chronic cholecystitis and cholelithiasis.
- Masson trichrome stain supports the diagnosis.

[page 2 of 2]
Patient Name:
Medical Record #:
Accession #:

Page

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and I have personally issued this report."

Resident/Prosector/Pathologist.
ICD9 Codes: 155.0 070.9 575.11 574.20
Diagnostic/Retrieval Codes: T

Note: Test systems have been developed and their performance characteristics determined by :
approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Some tests have not been cleared or

Pathologist
Electronically signed

Source: NCI Genomic Data Commons file 23324323-2c2b-4a3a-b6a8-f5efc0b30d11 (TCGA-ES-A2HT.FF97C711-0686-480B-BC53-3CADCAA4C4C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).